Gene-level copy-number profile of tumor specimen HTMCP-03-06-02155-01A from CGCI case HTMCP-03-06-02155, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 42.3 years (15,442 days).
Specimen HTMCP-03-06-02155-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 70d2bd19-c72f-41ae-9cc0-59ef32029ebf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02155-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/9259c34b-9df4-4be6-9291-bbf01f61a8e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,098; copy number 2: 42,530; copy number 3: 10,157; copy number 4: 521; copy number 5: 89.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,358,177, 3 genes, copy number 5: UGT2B28, AC114786.3, AC114786.2.
- chr4:69,408,828–69,423,164, 1 gene, copy number 5 (within-gene range 2–5): UGT2B24P.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes, copy number 5 (within-gene range 3–5): TRGV5P, TRGV5, TRGV4.
- chr14:22,066,016–22,503,814, 63 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr15:70,768,011–70,791,486, 2 genes, copy number 5: AC009269.3, AC009269.1.

Autosomal genes at a single copy (total copy number 1): 5,089. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
